Somatic mutation profile of tumor specimen TCGA-77-7141-01A (aliquot TCGA-77-7141-01A-11D-2042-08) from TCGA case TCGA-77-7141, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.6 years (23,584 days).
Specimen TCGA-77-7141-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d84ed8f-d1b7-410b-91ae-c7e6c90007f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-7141-11A (Solid Tissue Normal), aliquot TCGA-77-7141-11A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67e91ce5-20ea-4ecc-9172-fdbffde71177

The open-access MAF lists 688 somatic variants for this specimen: 506 protein-altering or splice-affecting, 163 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 463, Silent 163, Nonsense Mutation 25, Splice Site 8, Intron 8, Frame Shift Del 6, RNA 6, Splice Region 3, 5'UTR 2, 3'Flank 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADPRS | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as rs200626873, COSV99255576; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTC | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72556277, CM020170, COSV99234274; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABCB7 | c.1049G>C p.R350T (on ENST00000373394 / NM_001271696.3; = p.R351T on NM_004299.6) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99504612; called by muse, mutect2
- ABCG8 | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.78); catalogued as COSV99700068; called by muse, mutect2
- ABHD2 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100756395; called by muse, mutect2, varscan2
- ACSS3 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54096233, COSV54104713; called by muse, mutect2, varscan2
- ADAMTS2 | c.3171C>G p.I1057M | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV99283223; called by muse, mutect2, varscan2
- ADAR | c.2503C>G p.L835V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99426394; called by muse, mutect2
- ADGRE5 | c.584T>G p.I195S | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV99663099; called by muse, mutect2, varscan2
- ADGRL4 | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100876305; called by muse, mutect2, varscan2
- ADGRV1 | c.7736T>C p.V2579A | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV101316243; called by muse, mutect2, varscan2
- AFAP1L2 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100412801; called by muse, mutect2, varscan2
- AGAP2 | c.2057G>A p.R686Q (on ENST00000547588 / NM_001122772.2; = p.R350Q on NM_014770.4) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57729592; called by muse, mutect2, varscan2
- AMER2 | c.1988C>G p.A663G | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100766336; called by muse, mutect2, varscan2
- AMPD1 | c.1235A>T p.Y412F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815149; called by muse, mutect2, varscan2
- ANGPTL1 | c.848C>G p.A283G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99328294; called by muse, mutect2, varscan2
- ANK2 | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1393086626, COSV52154632; called by muse, mutect2, varscan2
- ANKLE2 | c.2409G>C p.L803F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs572111545, COSV100514262; called by muse, mutect2, varscan2
- ANKRD11 | c.4879G>A p.A1627T | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99970122; called by muse, mutect2
- ANKRD30A | c.1554G>T p.K518N (on ENST00000611781; = p.K462N on NM_052997.2) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV100654094, COSV64605561; called by muse, mutect2, varscan2
- APOA4 | c.928T>C p.Y310H | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.132); catalogued as COSV100759370; called by muse, mutect2, varscan2
- APOH | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.171); catalogued as COSV99235896; called by muse, mutect2, varscan2
- ARHGAP31 | c.2985G>T p.E995D | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV99957426; called by muse, mutect2, varscan2
- ARHGAP32 | c.4062G>T p.M1354I (on ENST00000310343 / NM_001378025.1; = p.M1005I on NM_014715.4) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); catalogued as COSV100088516; called by muse, mutect2, varscan2
- ARHGAP45 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV100490949; called by muse, mutect2
- ARHGEF12 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100755080; called by muse, mutect2
- ARID3B | c.1646G>A p.G549D (on ENST00000622429 / NM_001307939.1; = p.G548D on NM_006465.4) | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100654692; called by muse, mutect2
- ARMC6 | c.211A>G p.N71D (on ENST00000392336; = p.N46D on NM_033415.4) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV99523117; called by muse, mutect2, varscan2
- ATP1A2 | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 51/109 reads (47%) | catalogued as COSV100768023; called by muse, mutect2, varscan2
- B3GNT5 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 103/231 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs770404604, COSV58475469; called by muse, mutect2, varscan2
- BDH1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100827194, COSV64017737; called by muse, mutect2
- BDP1 | c.5388-2A>T p.X1796_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100703362; called by muse, mutect2, varscan2
- BEND3 | c.1628A>T p.Q543L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100944644; called by muse, mutect2, varscan2
- BNIP5 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV101465190; called by muse, mutect2, varscan2
- BOC | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.801); catalogued as COSV99849070; called by muse, mutect2, varscan2
- BRINP1 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV99776302; called by muse, mutect2, varscan2
- BRPF3 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs750899542, COSV60205646, COSV60205776; called by muse, mutect2, varscan2
- BTBD3 | c.1271C>G p.A424G | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99656009; called by muse, mutect2, varscan2
- C1QTNF3 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99180721; called by muse, mutect2, varscan2
- C6orf58 | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100314993; called by muse, varscan2
- CACNA1E | c.5023G>A p.E1675K | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV100704216; called by muse, mutect2
- CACNA1G | c.5988C>A p.C1996* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100662207; called by muse, mutect2, varscan2
- CACNA2D1 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100666968; called by muse, varscan2
- CCDC158 | c.1025A>G p.D342G | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101187305; called by muse, mutect2, varscan2
- CCDC18 | c.3646G>T p.E1216* (on ENST00000343253 / NM_001306076.1; = p.E1217* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100159804; called by muse, mutect2, varscan2
- CCDC191 | c.296T>G p.L99* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV99878538; called by muse, mutect2, varscan2
- CCNT1 | c.1418_1419insT p.S474Vfs*18 | Frame Shift Ins (INS) | VAF 20/73 reads (27%) | catalogued as COSV99980839; called by mutect2, pindel, varscan2
- CCT2 | c.1313C>G p.S438C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100167752; called by muse, mutect2
- CCT7 | c.1104G>C p.K368N | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as COSV99241020; called by muse, varscan2
- CCT8L2 | c.188T>A p.M63K | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100742935; called by muse, mutect2, varscan2
- CD109 | c.3268G>T p.A1090S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.238); catalogued as COSV99754143; called by muse, varscan2
- CD1B | c.471C>A p.S157R | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV100939265; called by muse, mutect2
- CDC20B | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99697213; called by muse, mutect2, varscan2
- CDH10 | c.2272G>A p.G758R | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as COSV100052379; called by muse, mutect2, varscan2
- CDH20 | c.641T>C p.F214S | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99406029; called by muse, mutect2
- CENPJ | c.2001G>C p.L667F | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV101121550; called by muse, mutect2, varscan2
- CEP112 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as rs1433431184, COSV101210966; called by muse, mutect2
- CEP126 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.159); catalogued as COSV99681278; called by muse, mutect2
- CFHR2 | c.230G>C p.W77S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100804368, COSV100804413; called by muse, mutect2, varscan2
- CFHR4 | c.1645T>A p.C549S (on ENST00000367416 / NM_001201551.2; = p.C303S on NM_006684.5) | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760376271, COSV99261094; called by muse, mutect2, varscan2
- CHD5 | c.4918G>T p.V1640L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV99314385; called by muse, mutect2, varscan2
- CHST1 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV100346394; called by muse, mutect2, varscan2
- CLASP2 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 118/186 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100223956; called by muse, mutect2, varscan2
- CLEC12B | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV100139066; called by muse, mutect2, varscan2
- CLEC17A | c.530T>A p.V177E | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100355474; called by muse, mutect2
- CLK1 | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1181693416, COSV100362382; called by muse, varscan2
- CLMN | c.1415A>G p.K472R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV100112717; called by muse, mutect2
- CNP | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV100348010; called by muse, mutect2
- CNR1 | c.146C>A p.P49H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.84); catalogued as COSV100759276; called by muse, mutect2, varscan2
- CNTN1 | c.851G>T p.S284I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV61636390; called by muse, mutect2, varscan2
- CNTN2 | c.75G>C p.W25C | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.299); catalogued as COSV100085300; called by muse, mutect2, varscan2
- COBL | c.1529A>T p.D510V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99473458; called by muse, mutect2, varscan2
- COL15A1 | c.286G>C p.V96L | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100897865; called by muse, mutect2
- COL1A1 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM930140, COSV56803737, COSV56809422; called by muse, mutect2, varscan2
- COL4A3 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.111); catalogued as COSV101170447; called by muse, mutect2, varscan2
- CORIN | c.1780C>G p.L594V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV99904084; called by muse, mutect2, varscan2
- COX10 | c.804C>A p.F268L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as COSV99886844; called by muse, mutect2, varscan2
- CPA5 | c.637-1G>T p.X213_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100812271; called by muse, mutect2, varscan2
- CPN1 | c.277C>A p.R93S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100962667; called by muse, mutect2, varscan2
- CPS1 | c.3833T>A p.V1278E | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV99243629; called by muse, mutect2, varscan2
- CPVL | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV99606198; called by muse, mutect2, varscan2
- CPXCR1 | c.197C>A p.A66E | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV99342319; called by muse, mutect2, varscan2
- CREB3L3 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV99314350; called by muse, mutect2, varscan2
- CRTC1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 104/292 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV100119460; called by muse, varscan2
- CSF2RB | c.93G>C p.Q31H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV99454190; called by muse, mutect2, varscan2
- CSMD2 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.702); catalogued as COSV99592858; called by muse, mutect2, varscan2
- CSMD3 | c.4042A>T p.S1348C (on ENST00000297405 / NM_001363185.1; = p.S1244C on NM_052900.3) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99841476; called by muse, mutect2, varscan2
- CSMD3 | c.11T>G p.I4S | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99841481; called by muse, mutect2, varscan2
- CUBN | c.9571G>T p.A3191S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV100913150; called by muse, mutect2, varscan2
- CUBN | c.9237-2A>T p.X3079_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as COSV64714964; called by muse, mutect2
- CUX1 | c.2959C>A p.P987T | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99472407; called by muse, mutect2, varscan2
- CUX2 | c.3440C>T p.P1147L | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs373425760, COSV55641948; called by muse, mutect2, varscan2
- CYP27B1 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.034); catalogued as COSV99141611; called by muse, mutect2
- DACT1 | c.1756C>A p.H586N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.215); catalogued as COSV100241998; called by muse, mutect2, varscan2
- DCP1A | c.1732G>C p.D578H | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99588103; called by muse, mutect2, varscan2
- DDI1 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs1361081860, COSV100160123, COSV56380276; called by muse, mutect2, varscan2
- DGKB | c.1651A>C p.I551L | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV99341698; called by muse, mutect2
- DIAPH3 | c.282G>C p.K94N | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV57369691, COSV99934010; called by muse, mutect2, varscan2
- DIDO1 | c.2698G>A p.D900N | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.343); catalogued as COSV99826529; called by muse, mutect2, varscan2
- DISP1 | c.2850G>T p.W950C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99451642; called by muse, mutect2, varscan2
- DIXDC1 | c.1524A>T p.R508S (on ENST00000440460 / NM_001037954.4; = p.R297S on NM_033425.4) | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV100180366; called by muse, mutect2, varscan2
- DMXL1 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV100224504; called by mutect2, varscan2
- DNAH11 | c.3600G>T p.L1200F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100179939; called by muse, mutect2, varscan2
- DNAH7 | c.6046C>G p.Q2016E | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100416399; called by muse, mutect2
- DNAJB14 | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100508566; called by muse, mutect2, varscan2
- DND1 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100298160; called by muse, mutect2, varscan2
- DOCK9 | c.418A>C p.K140Q (on ENST00000376460 / NM_001366676.2; = p.K141Q on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/95 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100240219; called by muse, mutect2
- DPH6 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV99853767; called by muse, mutect2, varscan2
- DPPA4 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 31/121 reads (26%) | catalogued as COSV100169576, COSV59511410; called by muse, mutect2, varscan2
- DSCAM | c.5004G>C p.L1668F | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV101260989; called by muse, mutect2, varscan2
- DST | c.10474G>T p.V3492L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99751778, COSV99758395; called by muse, mutect2, varscan2
- DUSP5 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs758622968, COSV63647199; called by muse, mutect2, varscan2
- DUXA | c.430A>G p.R144G | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1180778844, COSV101617151; called by muse, mutect2
- DYNC2H1 | c.6505G>T p.V2169F | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100519164; called by muse, mutect2, varscan2
- EHMT2 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs781345814, COSV100977231; called by muse, mutect2, varscan2
- EIF2B4 | c.267G>C p.E89D (on ENST00000347454 / NM_001034116.2; = p.E88D on NM_015636.3) | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); catalogued as COSV52007235, COSV99277802; called by muse, mutect2
- EIF5B | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99177560; called by muse, mutect2, varscan2
- ELANE | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55047853, COSV55049390; called by muse, mutect2, varscan2
- EPHA5 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99900128; called by muse, mutect2, varscan2
- EPHA8 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as COSV99385304; called by muse, mutect2, varscan2
- EPHB6 | c.1996G>C p.V666L | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV100844372; called by muse, mutect2, varscan2
- ERBB4 | c.3725A>T p.Y1242F | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV100722631, COSV61476936; called by muse, mutect2, varscan2
- ERI3 | c.236T>C p.M79T | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs765761070, COSV100952193; called by muse, mutect2, varscan2
- ESAM | c.918G>C p.K306N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99632006; called by muse, mutect2, varscan2
- ESM1 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV101195690; called by muse, mutect2, varscan2
- ESS2 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.931); catalogued as COSV99351070; called by muse, mutect2, varscan2
- EVX2 | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV100420766, COSV57962885; called by muse, mutect2
- EXD1 | c.1537C>G p.L513V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.202); catalogued as rs1043680035, COSV100153767; called by muse, mutect2, varscan2
- EXOSC5 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54197166, COSV99524691; called by muse, mutect2
- FAM135B | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52728853, COSV99425888; called by muse, mutect2, varscan2
- FAM234B | c.1266G>C p.L422F | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.048); catalogued as rs1459802223, COSV99545831; called by muse, mutect2, varscan2
- FAM47B | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); catalogued as COSV100264489, COSV61453969; called by muse, mutect2, varscan2
- FAM47C | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as COSV63723950; called by muse, mutect2
- FANCD2 | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV55049967, COSV99811945; called by muse, mutect2, varscan2
- FASTKD2 | c.462C>G p.I154M | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV99379125; called by muse, mutect2, varscan2
- FAT1 | c.2818C>A p.L940I | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.721); catalogued as COSV101499486; called by muse, mutect2
- FBLN7 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); catalogued as COSV99734946; called by muse, mutect2, varscan2
- FBXL12 | c.160-1G>A p.X54_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99928088; called by muse, mutect2, varscan2
- FBXO47 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV100960803; called by muse, mutect2
- FCN1 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV100878942, COSV65662886; called by muse, mutect2, varscan2
- FCRL2 | c.1387G>T p.V463F | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV100829964; called by muse, mutect2, varscan2
- FCRL4 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV54861201, COSV99620154; called by muse, mutect2
- FGFR2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.382); catalogued as rs938460066, CM078275, COSV99050120; called by muse, mutect2, varscan2
- FIS1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV99778979; called by muse, mutect2
- FLI1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as rs565481092, COSV99857948; called by muse, varscan2
- FMN2 | c.2969C>A p.P990H | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs761327375, COSV100146464; called by muse, mutect2, varscan2
- FMO1 | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.446); catalogued as COSV100707860; called by muse, mutect2
- FNDC3A | c.3437A>T p.Q1146L (on ENST00000492622 / NM_001079673.2; = p.Q1090L on NM_014923.5) | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.11); PolyPhen benign (0.25); catalogued as COSV68135114; called by muse, mutect2, varscan2
- FRAS1 | c.1878C>A p.C626* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99354303; called by muse, mutect2, varscan2
- FRMPD1 | c.3630C>G p.F1210L | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV100899599; called by muse, mutect2
- FSCB | c.257A>T p.K86M | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.591); catalogued as COSV100469617; called by muse, mutect2, varscan2
- FTO | c.114C>G p.F38L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780803760, COSV101150827; called by muse, mutect2, varscan2
- FXN | c.392C>G p.S131C (on ENST00000377270; = p.S206C on NM_000144.5) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101040141, COSV66010448; called by muse, mutect2
- FXR1 | c.571A>G p.S191G | Missense Mutation (SNP) | VAF 56/380 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV99976537; called by muse, mutect2, varscan2
- GAB2 | c.1348G>A p.D450N (on ENST00000361507 / NM_080491.3; = p.D412N on NM_012296.3) | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100416656, COSV60867008; called by muse, mutect2
- GABRG2 | c.74T>G p.V25G | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV100729782; called by muse, mutect2, varscan2
- GAD1 | c.868A>T p.S290C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV100713886; called by muse, mutect2, varscan2
- GALR1 | c.477C>G p.I159M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552581288, COSV100231974; called by muse, mutect2, varscan2
- GAN | c.1379G>C p.G460A | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as COSV101634018; called by muse, mutect2, varscan2
- GAST | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100268072; called by muse, varscan2
- GCN1 | c.2512C>G p.L838V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV100325698; called by muse, mutect2
- GFI1 | c.226del p.E76Kfs*122 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as COSV54043001; called by mutect2, pindel, varscan2
- GFPT2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs1351075199, COSV99517919; called by mutect2, varscan2
- GIPC2 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV99503827; called by muse, mutect2, varscan2
- GLMN | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100950124; called by muse, mutect2, varscan2
- GLYATL2 | c.189G>A p.E63= | Splice Region (SNP) | VAF 25/70 reads (36%) | catalogued as COSV54851332, COSV99780468; called by muse, mutect2, varscan2
- GNAZ | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV50742770, COSV99321027; called by muse, mutect2, varscan2
- GPRC5C | c.1127A>T p.Q376L (on ENST00000652232; = p.Q331L on NM_018653.4) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV100702952; called by muse, mutect2, varscan2
- GRB14 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV55738290; called by muse, mutect2, varscan2
- GRM1 | c.1016C>A p.T339K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51196292, COSV99267739; called by muse, mutect2
- GSDMD | c.955G>T p.V319L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs1034452031, COSV99369513; called by muse, mutect2, varscan2
- GSG1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 95/251 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs749064336, COSV100189392; called by muse, mutect2, varscan2
- GSPT2 | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV100468265; called by muse, mutect2
- GSTA2 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 64/132 reads (48%) | catalogued as COSV101534061; called by muse, mutect2, varscan2
- H2AC16 | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100511355; called by muse, mutect2, varscan2
- H2BC12 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 19/293 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.227); catalogued as COSV100804720; called by muse, mutect2
- HAUS7 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100444065, COSV57850202; called by muse, mutect2, varscan2
- HAVCR2 | c.750G>C p.L250F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV100324873; called by muse, mutect2, varscan2
- HELZ2 | c.3007G>C p.E1003Q (on ENST00000467148 / NM_001037335.2; = p.E434Q on NM_033405.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.029); catalogued as COSV100915646, COSV99069525; called by muse, mutect2
- HERC1 | c.5108T>C p.L1703S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101496746; called by muse, mutect2, varscan2
- HGF | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV55957208, COSV99737851; called by muse, mutect2
- HMCN1 | c.15974C>G p.P5325R | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99632713; called by muse, mutect2
- HNRNPA0 | c.856A>G p.N286D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV100152927; called by muse, mutect2, varscan2
- HS6ST3 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV100941111, COSV65020684; called by muse, mutect2, varscan2
- HSPA9 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs760801530, COSV99785604; called by muse, mutect2, varscan2
- HTATSF1 | c.749G>T p.R250I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV99511791; called by muse, mutect2, varscan2
- HTR2C | c.1272C>G p.I424M | Missense Mutation (SNP) | VAF 84/115 reads (73%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV99350250, COSV99350965; called by muse, mutect2, varscan2
- ICAM5 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV55749440, COSV99703450; called by muse, mutect2, varscan2
- IDO2 | c.523G>C p.E175Q (on ENST00000389060; = p.E188Q on NM_194294.2) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100584876; called by muse, mutect2
- IGF2R | c.7040C>G p.S2347C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100807848; called by muse, mutect2, varscan2
- IGKV1D-16 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1303917349; called by muse, varscan2
- IGSF9B | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.079); catalogued as COSV100318102; called by muse, mutect2, varscan2
- IMPDH2 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 26/145 reads (18%) | catalogued as COSV100455123; called by muse, mutect2, varscan2
- INSRR | c.2923C>A p.P975T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV100947851; called by muse, mutect2, varscan2
- IPO8 | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as COSV99805477, COSV99805518; called by muse, mutect2
- IQGAP2 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.101); catalogued as COSV99167772; called by muse, mutect2, varscan2
- IRF2 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 49/77 reads (64%) | catalogued as COSV101165867, COSV66928529, COSV66929484; called by muse, mutect2, varscan2
- IRGQ | c.1793A>C p.H598P | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100338222; called by muse, mutect2, varscan2
- IRX1 | c.1121G>C p.W374S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100116652, COSV99042694; called by muse, mutect2, varscan2
- ITGAD | c.2846A>C p.E949A | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV99791448; called by muse, mutect2
- ITIH2 | c.2183T>A p.L728H | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100623346; called by muse, mutect2
- KBTBD4 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99772408; called by muse, mutect2, varscan2
- KCNH6 | c.1084C>A p.R362S | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.049); catalogued as COSV100121164; called by muse, mutect2, varscan2
- KCNU1 | c.1502T>C p.V501A | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.575); catalogued as COSV101299351; called by muse, mutect2
- KCNV2 | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV101172626, COSV66056702; called by muse, mutect2
- KHDRBS2 | c.581G>C p.G194A | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55499156, COSV99835833; called by muse, mutect2, varscan2
- KHNYN | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99249938; called by muse, mutect2, varscan2
- KIR3DL1 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.026); catalogued as rs1313222690, COSV100373252; called by muse, mutect2
- KIRREL2 | c.722del p.G241Efs*36 | Frame Shift Del (DEL) | VAF 47/90 reads (52%) | catalogued as COSV52877713; called by mutect2, pindel, varscan2
- KLHL1 | c.1183A>T p.S395C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100917758; called by muse, mutect2, varscan2
- KMT2D | c.7591C>T p.P2531S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs371432516, COSV99984240; called by muse, mutect2, varscan2
- KMT5C | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99726264; called by muse, mutect2, varscan2
- KRT35 | c.1279C>G p.L427V | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV99877852; called by muse, mutect2, varscan2
- KRTAP10-12 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV100554717, COSV100555019; called by muse, mutect2, varscan2
- KRTAP4-12 | c.484C>A p.R162S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV101224284; called by muse, mutect2, varscan2
- L3MBTL3 | c.1001-1G>T p.X334_splice | Splice Site (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100696306; called by muse, mutect2, varscan2
- LCT | c.3604G>A p.D1202N | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315896065, COSV99930012; called by muse, mutect2, varscan2
- LGALS2 | c.384C>G p.F128L | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99312594; called by muse, mutect2
- LIPI | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100753876; called by muse, varscan2
- LRP1B | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101258495; called by muse, mutect2, varscan2
- LRRC4B | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.991); catalogued as rs1568714208, COSV65350829; called by muse, mutect2, varscan2
- LTN1 | c.2882T>G p.L961R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100798085; called by muse, mutect2, varscan2
- MACF1 | c.18415G>T p.V6139F (on ENST00000372915; = p.V4184F on NM_012090.5) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99245817; called by muse, mutect2, varscan2
- MAG | c.66G>C p.W22C | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100727725, COSV100727972; called by muse, mutect2, varscan2
- MAGEB1 | c.689A>T p.Y230F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.819); catalogued as COSV66775446; called by muse, mutect2, varscan2
- MAGEC2 | c.316T>A p.S106T | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.874); catalogued as COSV56000667, COSV99909772; called by muse, mutect2, varscan2
- MAGI2 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV100835526; called by muse, mutect2, varscan2
- MAP2 | c.4669G>C p.D1557H | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99561103; called by muse, mutect2
- MAST1 | c.472C>G p.R158G | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99262546, COSV99263354; called by muse, mutect2, varscan2
- MAST4 | c.3410G>T p.S1137I (on ENST00000403625 / NM_001164664.2; = p.S948I on NM_015183.3) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV99845064; called by muse, mutect2, varscan2
- MEIOC | c.1058T>G p.L353* | Nonsense Mutation (SNP) | VAF 14/21 reads (67%) | catalogued as COSV100740273; called by muse, mutect2, varscan2
- MEX3B | c.1099C>G p.P367A | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.067); catalogued as COSV100314163; called by muse, mutect2, varscan2
- MFN2 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99336912; called by muse, mutect2, varscan2
- MFSD6 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972401389, COSV99855301; called by muse, mutect2, varscan2
- MGAT4B | c.1422+1G>T p.X474_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | catalogued as rs917239218, COSV52977810, COSV99482293; called by muse, mutect2, varscan2
- MKI67 | c.8263G>T p.E2755* | Nonsense Mutation (SNP) | VAF 34/135 reads (25%) | catalogued as COSV100896413; called by muse, mutect2, varscan2
- MKI67 | c.1268G>C p.R423T | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100896836; called by muse, mutect2
- MKI67 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as COSV100896837; called by muse, mutect2, varscan2
- MNAT1 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as rs761974468, COSV54187737; called by muse, mutect2, varscan2
- MPV17L2 | c.499C>G p.R167G | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55852076, COSV99718057; called by muse, mutect2, varscan2
- MRPS2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs747619062, COSV99613577; called by muse, mutect2, varscan2
- MTUS1 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV100029770; called by muse, mutect2, varscan2
- MTUS2 | c.1669G>T p.D557Y | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101462307, COSV70917275; called by muse, mutect2, varscan2
- MUC16 | c.17382C>A p.N5794K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV101200579; called by muse, mutect2, varscan2
- MUC4 | c.2936T>C p.V979A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.159); catalogued as COSV100641448; called by muse, mutect2
- MUC5AC | c.1788C>G p.F596L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); catalogued as COSV100650646; called by muse, mutect2, varscan2
- MYBPC2 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs781519827, COSV100731931; called by muse, mutect2, varscan2
- MYH1 | c.1856C>G p.T619S | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV99876502; called by muse, mutect2, varscan2
- MYH4 | c.2359C>G p.Q787E | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55115189; called by muse, mutect2, varscan2
- MYL2 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99960827; called by muse, varscan2
- MYO3B | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100511072; called by muse, mutect2, varscan2
- NAT1 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100306548; called by muse, mutect2
- NAV3 | c.2626G>T p.D876Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV57115670, COSV99895513; called by muse, mutect2, varscan2
- NCAPD3 | c.4328-1G>C p.X1443_splice | Splice Site (SNP) | VAF 11/222 reads (5%) | catalogued as COSV54449985; called by muse, mutect2
- NCKAP1L | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99515436; called by muse, mutect2, varscan2
- NCKAP5 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100493524; called by muse, mutect2, varscan2
- NEBL | c.2395C>A p.P799T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV101009287; called by mutect2, varscan2
- NEK5 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.355); catalogued as COSV100839273; called by muse, mutect2, varscan2
- NFE2 | c.338C>G p.S113* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | catalogued as COSV56455235, COSV56455351; called by muse, mutect2
- NID2 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs375366746; called by muse, mutect2, varscan2
- NIFK | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 28/58 reads (48%) | catalogued as COSV99590536, COSV99590685; called by muse, mutect2, varscan2
- NISCH | c.1510C>G p.P504A | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.8); catalogued as COSV100617519; called by muse, mutect2, varscan2
- NLGN1 | c.1445C>G p.P482R | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV100849743; called by muse, mutect2, varscan2
- NLGN4X | c.2190G>A p.M730I | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.062); catalogued as rs770882050, COSV99322421, COSV99323025; called by muse, mutect2, varscan2
- NLRP12 | c.2329C>G p.L777V | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100145559; called by muse, mutect2
- NLRP13 | c.1984G>C p.D662H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV100738134; called by muse, mutect2, varscan2
- NLRP14 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV100205244; called by muse, mutect2
- NMRAL1 | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99361853; called by mutect2, varscan2
- NMT1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV99364903; called by muse, mutect2
- NOP14 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100054884; called by muse, mutect2, varscan2
- NOP56 | c.1446G>C p.K482N | Missense Mutation (SNP) | VAF 27/316 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100250245; called by muse, mutect2
- NOVA2 | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99611497; called by muse, mutect2, varscan2
- NRXN1 | c.435G>T p.R145S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.04); catalogued as rs1303388955, COSV101278291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSD1 | c.4099G>C p.E1367Q | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV61784946; called by muse, mutect2
- NTM | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV100869103, COSV66172926; called by muse, mutect2, varscan2
- NUGGC | c.1705C>G p.L569V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.861); catalogued as COSV100429541, COSV58434193; called by muse, mutect2, varscan2
- NWD1 | c.992G>T p.S331I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.451); catalogued as COSV100343287; called by muse, mutect2, varscan2
- NYAP1 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100278593; called by muse, mutect2
- OGT | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV101035543; called by muse, mutect2
- OR10T2 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100555037; called by muse, mutect2, varscan2
- OR12D3 | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101011387; called by muse, mutect2
- OR2A25 | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101376405; called by muse, mutect2, varscan2
- OR2B3 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV101013828; called by muse, mutect2, varscan2
- OR2F2 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101283836; called by muse, mutect2, varscan2
- OR2G2 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV100189848; called by muse, mutect2, varscan2
- OR2J2 | c.182A>T p.Y61F | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101013417; called by muse, mutect2, varscan2
- OR2J3 | c.232A>T p.T78S | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as COSV101013647, COSV101013676; called by muse, mutect2, varscan2
- OR2W3 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64457139; called by muse, mutect2, varscan2
- OR4D5 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100190104; called by muse, mutect2, varscan2
- OR4D5 | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as COSV100190106, COSV58305894, COSV58306883; called by muse, mutect2, varscan2
- OR4Q3 | c.471C>A p.C157* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100057224; called by muse, mutect2, varscan2
- OR5K1 | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs778665748, COSV100221002; called by muse, mutect2, varscan2
- OR5M1 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV101591583; called by muse, mutect2, varscan2
- OR5R1 | c.476A>T p.H159L | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.906); catalogued as rs1416676457, COSV100393524; called by muse, mutect2
- OR6A2 | c.715C>A p.R239S | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV100215782, COSV60264834; called by muse, mutect2, varscan2
- OR8G1 | c.470C>G p.S157* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100422559; called by muse, mutect2, varscan2
- OR8G5 | c.23T>C p.F8S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100422561; called by muse, mutect2, varscan2
- OR8H2 | c.908G>A p.R303K | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV100542410; called by muse, mutect2, varscan2
- OR9Q2 | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.709); catalogued as COSV61111454, COSV61112073; called by muse, mutect2
- P2RY8 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101184113, COSV67176977, COSV67177114; called by muse, mutect2, varscan2
- PAK1 | c.351G>C p.Q117H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99583740; called by muse, mutect2
- PANX3 | c.1162T>C p.C388R | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99421688; called by muse, mutect2, varscan2
- PAPPA | c.3572G>C p.S1191T | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.321); catalogued as COSV100074794; called by muse, mutect2, varscan2
- PARP2 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.328); catalogued as rs375344456; called by mutect2, varscan2
- PAX1 | c.1507C>G p.R503G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV101270162, COSV101270345; called by muse, mutect2, varscan2
- PCDH11Y | c.1919C>G p.S640C (on ENST00000400457 / NM_032973.2; = p.S629C on NM_032971.3) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99292195; called by muse, mutect2, varscan2
- PCDH15 | c.3848A>T p.K1283M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV100224571; called by muse, varscan2
- PCDH8 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV58810775; called by muse, mutect2, varscan2
- PCDHA1 | c.1910T>C p.L637P | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100974408; called by muse, mutect2, varscan2
- PCDHB12 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1441936667, COSV99507569; called by muse, mutect2, varscan2
- PCDHB6 | c.2015C>G p.P672R | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV99170540; called by muse, mutect2, varscan2
- PCOLCE | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99775284; called by muse, mutect2, varscan2
- PDGFB | c.660G>T p.K220N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100483564, COSV58647222; called by muse, mutect2, varscan2
- PDZRN3 | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99730997; called by muse, mutect2, varscan2
- PDZRN3 | c.1683G>T p.L561F | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99731004; called by muse, mutect2, varscan2
- PEBP4 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99835248; called by muse, mutect2
- PEG3 | c.3592G>C p.D1198H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV55641595, COSV99689735; called by muse, mutect2
- PGAP6 | c.1690G>T p.V564F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99170747; called by muse, mutect2, varscan2
- PIKFYVE | c.6133A>T p.K2045* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100011152; called by muse, mutect2, varscan2
- PKHD1 | c.5846A>G p.E1949G | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs751894216, COSV100583913, COSV61898707; called by muse, mutect2, varscan2
- PKHD1L1 | c.3229G>A p.G1077R | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101006600; called by muse, mutect2, varscan2
- PLCB1 | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.065); catalogued as COSV100571737; called by muse, mutect2, varscan2
- PLCH1 | c.3286G>C p.V1096L (on ENST00000340059 / NM_001130960.2; = p.V1088L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/391 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs751691768, COSV100397663, COSV58193087; called by muse, mutect2, varscan2
- PLD5 | c.313C>A p.Q105K (on ENST00000442594; = p.Q43K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV100141684; called by muse, mutect2, varscan2
- PLEKHG4B | c.2434G>A p.E812K (on ENST00000283426; = p.E1168K on NM_052909.5) | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770404592, COSV99360763; called by muse, mutect2, varscan2
- PLEKHH1 | c.3642C>G p.I1214M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV100233357; called by muse, mutect2, varscan2
- PLEKHS1 | c.95C>T p.S32F (on ENST00000369310 / NM_182601.1; = p.S38F on NM_024889.5) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100732898; called by muse, mutect2, varscan2
- PLEKHS1 | c.758C>A p.S253Y (on ENST00000369310 / NM_182601.1; = p.S259Y on NM_024889.5) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100613233; called by muse, mutect2, varscan2
- PLOD2 | c.95C>G p.S32W | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV51462248, COSV99283059; called by muse, mutect2
- PNISR | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100984396; called by muse, mutect2
- POM121L12 | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as COSV101374952; called by muse, mutect2, varscan2
- POM121L12 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV68692484; called by muse, mutect2, varscan2
- POU4F2 | c.110C>G p.S37W | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); catalogued as COSV55584183; called by muse, mutect2
- PPP1R7 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV99298076; called by muse, mutect2, varscan2
- PRAG1 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV100422517; called by muse, mutect2, varscan2
- PRAMEF1 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.42); catalogued as rs572373336, COSV60011794; called by muse, mutect2, varscan2
- PRF1 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100942656; called by muse, mutect2
- PROKR2 | c.763G>C p.V255L | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as COSV99450482; called by muse, mutect2
- PRPF8 | c.6131C>A p.T2044N | Missense Mutation (SNP) | VAF 75/128 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV100025483; called by muse, mutect2, varscan2
- PRR14 | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99788560; called by muse, mutect2, varscan2
- PRRC2C | c.4469C>G p.S1490C (on ENST00000367742; = p.S1488C on NM_015172.4) | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100145603; called by muse, mutect2
- PRSS16 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV100041864; called by muse, mutect2, varscan2
- PSENEN | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99495321; called by muse, mutect2, varscan2
- PSMC3IP | c.565G>A p.E189K (on ENST00000393795 / NM_016556.4; = p.E177K on NM_013290.6) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777578702, COSV99519026; called by muse, mutect2, varscan2
- PTPRD | c.4114T>C p.W1372R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100645853; called by muse, mutect2, varscan2
- PTPRG | c.3769G>A p.E1257K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV55664121; called by muse, mutect2
- PTTG2 | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV99791757; called by muse, mutect2, varscan2
- PXDNL | c.3463G>C p.D1155H | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100685080; called by muse, varscan2
- PYGM | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV99377389; called by muse, varscan2
- RABAC1 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99706067; called by muse, mutect2, varscan2
- RAI1 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as rs1256621621, COSV99884612; called by muse, mutect2, varscan2
- RANBP2 | c.5924G>T p.G1975V | Missense Mutation (SNP) | VAF 126/333 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99312762; called by muse, mutect2, varscan2
- RASGEF1B | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs760854157, COSV52336077; called by muse, mutect2, varscan2
- RBM17 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs1269099008, COSV101159140; called by muse, mutect2, varscan2
- RELN | c.4160G>C p.R1387P | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100634332, COSV59020316; called by muse, mutect2
- RELN | c.614A>T p.D205V | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100634334; called by muse, mutect2
- RERE | c.4486G>A p.G1496S | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs202052220; called by muse, varscan2
- RGS20 | c.537G>A p.M179I (on ENST00000297313 / NM_170587.4; = p.M32I on NM_003702.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs764557978, COSV99392380; called by muse, mutect2, varscan2
- RIF1 | c.4220T>G p.I1407R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV99690915; called by muse, mutect2
- RIPOR2 | c.1421A>T p.Q474L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as COSV99429725; called by muse, mutect2, varscan2
- RNF166 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.067); catalogued as COSV100455524; called by muse, mutect2, varscan2
- RNF17 | c.1913C>G p.S638C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99693895; called by muse, mutect2
- RNF17 | c.3148C>G p.L1050V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV99693903; called by muse, mutect2, varscan2
- RNLS | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100076811; called by muse, mutect2, varscan2
- ROBO1 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as rs1320282147, COSV71393849; called by muse, mutect2
- ROBO3 | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as rs1174813019, COSV101185126; called by muse, mutect2, varscan2
- RORA | c.733T>A p.C245S (on ENST00000335670 / NM_134261.3; = p.C270S on NM_002943.3) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV99832913; called by muse, mutect2, varscan2
- RP9 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs762365872, COSV99778021; called by muse, mutect2, varscan2
- RPGRIP1L | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV50903125; called by muse, mutect2, varscan2
- RPH3A | c.1319C>A p.A440D (on ENST00000389385 / NM_001143854.2; = p.A436D on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV101231862; called by muse, mutect2, varscan2
- RUVBL1 | c.308C>A p.S103* | Nonsense Mutation (SNP) | VAF 9/155 reads (6%) | catalogued as COSV100494234, COSV59475801; called by muse, mutect2
- RYR2 | c.5155C>A p.L1719I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as COSV100772031; called by muse, mutect2, varscan2
- SBDS | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV55887530; called by muse, mutect2, varscan2
- SCN4A | c.3283A>C p.N1095H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101438580; called by muse, mutect2, varscan2
- SCUBE1 | c.2767C>A p.R923S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62611258, COSV62612465; called by muse, mutect2, varscan2
- SCYL1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.731); catalogued as rs370357462; called by muse, mutect2, varscan2
- SEC23B | c.433C>G p.Q145E | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV99357921; called by mutect2, varscan2
- SENP2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99958041; called by muse, mutect2, varscan2
- SERHL2 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as COSV100243637; called by muse, mutect2, varscan2
- SETD2 | c.3905G>A p.G1302D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs1348000790, COSV100339569; called by muse, mutect2, varscan2
- SFMBT2 | c.525T>A p.G175= | Splice Region (SNP) | VAF 53/188 reads (28%) | catalogued as COSV100739327; called by muse, mutect2, varscan2
- SH3GL2 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101014627; called by muse, mutect2, varscan2
- SHROOM2 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV101098903; called by muse, mutect2, varscan2
- SI | c.2441T>C p.L814P | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100016447; called by mutect2, varscan2
- SIGLEC7 | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV58314606, COSV99978844; called by muse, mutect2
- SLAMF6 | c.790G>C p.G264R | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100924912; called by muse, mutect2
- SLC17A8 | c.1341C>A p.S447R | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100035710; called by muse, mutect2, varscan2
- SLC26A2 | c.1922A>G p.H641R | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.158); catalogued as rs1253691463, CM156931, COSV99640276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC26A5 | c.840G>C p.E280D | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.034); catalogued as COSV100099799; called by muse, mutect2
- SLC2A5 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101072677; called by muse, mutect2, varscan2
- SLC39A12 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1554847357, COSV101070097; called by muse, mutect2
- SLC47A1 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 88/155 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99565517; called by muse, mutect2, varscan2
- SLC6A1 | c.1143G>T p.W381C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV99822990; called by muse, mutect2, varscan2
- SLC9C1 | c.2464C>G p.L822V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99998392, COSV99998629; called by muse, mutect2
- SLCO5A1 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52657012; called by muse, mutect2, varscan2
- SLITRK2 | c.565A>T p.R189W | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158026; called by muse, mutect2, varscan2
- SMPD1 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100192927; called by muse, mutect2, varscan2
- SNPH | c.564G>C p.Q188H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.987); catalogued as COSV100378300; called by muse, mutect2, varscan2
- SNRPB2 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV99855886; called by muse, mutect2
- SNX3 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV100018041; called by muse, mutect2, varscan2
- SNX30 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.51); PolyPhen benign (0.153); catalogued as rs747903060, COSV100953932; called by muse, mutect2, varscan2
- SOBP | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100433298; called by muse, mutect2, varscan2
- SOCS6 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV101205810, COSV67545922; called by muse, mutect2, varscan2
- SPAG17 | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100309858, COSV60453890; called by muse, mutect2, varscan2
- SPATA17 | c.872+1G>T p.X291_splice | Splice Site (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100861216; called by muse, mutect2, varscan2
- SPATA31D1 | c.3913G>C p.D1305H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100783045, COSV61201483; called by muse, mutect2, varscan2
- SPATA5 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99916019; called by muse, mutect2, varscan2
- SPEN | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs1156384525, COSV101005467; called by muse, mutect2, varscan2
- SPPL2B | c.1580C>G p.S527C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV101476111; called by muse, varscan2
- SPTA1 | c.3331G>C p.D1111H | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs760205675, COSV100935262, COSV63753783; called by muse, mutect2, varscan2
- SPTA1 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1049898003, COSV63757443; called by muse, mutect2, varscan2
- SRCAP | c.8441C>T p.S2814L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV99350794; called by muse, mutect2
- SRPK2 | c.1446G>C p.E482D | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as COSV100624193; called by muse, mutect2, varscan2
- SSX7 | c.463T>C p.S155P | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as COSV99993949; called by muse, mutect2
- ST8SIA1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.274); catalogued as rs753572987, COSV53956685; called by muse, mutect2, varscan2
- STARD13 | c.1306G>C p.E436Q (on ENST00000336934 / NM_001243476.3; = p.E318Q on NM_052851.3) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99716178; called by muse, mutect2, varscan2
- STXBP5L | c.2623C>G p.Q875E | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56537101, COSV99875404; called by muse, mutect2
- SUDS3 | c.210A>G p.E70= | Splice Region (SNP) | VAF 5/17 reads (29%) | catalogued as rs1449318119, COSV66916533; called by muse, mutect2, varscan2
- SUGP1 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.236); catalogued as COSV55924461, COSV99895329; called by muse, mutect2, varscan2
- SUPT16H | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99360058; called by muse, mutect2, varscan2
- SUPT3H | c.526G>C p.E176Q (on ENST00000371460 / NM_181356.3; = p.E165Q on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); catalogued as COSV100177717, COSV60947820; called by muse, mutect2, varscan2
- SYCP2 | c.3503A>T p.N1168I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs936762229, COSV100698369; called by muse, mutect2, varscan2
- SYT17 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100810812; called by muse, mutect2
- TAAR1 | c.556T>A p.F186I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV99257683; called by muse, mutect2, varscan2
- TAAR9 | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV101453370; called by muse, mutect2, varscan2
- TAGAP | c.1833G>C p.E611D | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV100487571; called by muse, mutect2, varscan2
- TAOK1 | c.2083C>T p.R695* | Nonsense Mutation (SNP) | VAF 32/97 reads (33%) | catalogued as COSV99914449; called by muse, mutect2, varscan2
- TAOK3 | c.2030T>C p.L677S | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV101183643; called by muse, mutect2, varscan2
- TAS2R16 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV99972303; called by muse, mutect2, varscan2
- TASOR2 | c.4589C>T p.S1530L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV60167671; called by muse, mutect2, varscan2
- TBX15 | c.616G>C p.G206R (on ENST00000369429 / NM_001330677.2; = p.G100R on NM_152380.3) | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99253744, COSV99254486; called by muse, mutect2, varscan2
- TBX22 | c.1552C>A p.H518N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV64788028; called by muse, mutect2, varscan2
- TCEA3 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1389185902, COSV101004641; called by muse, mutect2
- TDRD1 | c.3391G>T p.A1131S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.23); catalogued as COSV99314876; called by muse, mutect2, varscan2
- TDRD5 | c.341G>C p.G114A | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as COSV99676746; called by muse, mutect2
- TDRD6 | c.5145G>C p.E1715D | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100287980; called by muse, mutect2
- TECTA | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99880762; called by muse, mutect2, varscan2
- TEX47 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51878448, COSV99787342; called by muse, mutect2, varscan2
- THSD7B | c.3739G>A p.V1247M (on ENST00000272643; = p.V1245M on NM_001316349.2) | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs370520413; called by muse, varscan2
- TKFC | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.251); catalogued as rs368350098, COSV99582556; called by muse, mutect2
- TMC1 | c.2238G>C p.K746N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.118); catalogued as COSV52776679, COSV99920073; called by muse, mutect2, varscan2
- TMC3 | c.1132G>C p.D378H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100845961; called by muse, mutect2
- TMEM71 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100785666; called by muse, mutect2, varscan2
- TMEM79 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99828025; called by muse, mutect2, varscan2
- TMPRSS9 | c.1906C>A p.L636M (on ENST00000648592; = p.L602M on NM_182973.2) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100211558; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.178); catalogued as rs766945602, COSV100836156; called by muse, varscan2
- TNR | c.3959G>A p.G1320D | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1191117184, COSV99690628; called by muse, mutect2, varscan2
- TNR | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750178171, COSV99690629; called by muse, mutect2, varscan2
- TOPBP1 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99605607; called by muse, mutect2
- TRAK2 | c.2056C>G p.Q686E | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.389); catalogued as COSV100216997; called by muse, mutect2
- TRIM45 | c.1206T>G p.C402W | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99868645; called by muse, mutect2
- TRIM50 | c.529C>A p.R177S | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.549); catalogued as COSV100297243; called by muse, mutect2, varscan2
- TRPM8 | c.137A>C p.Q46P | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100224328; called by muse, mutect2, varscan2
- TSHZ3 | c.3211C>T p.H1071Y | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53663099, COSV99552192; called by muse, mutect2, varscan2
- TTLL3 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs765118646, COSV100047721; called by muse, mutect2, varscan2
- TTN | c.80615C>A p.T26872N (on ENST00000591111; = p.T19448N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | PolyPhen possibly damaging (0.848); catalogued as COSV100622060; called by muse, mutect2, varscan2
- TTN | c.61556C>T p.P20519L (on ENST00000591111; = p.P13095L on NM_003319.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | PolyPhen probably damaging (0.999); catalogued as rs777364605, COSV100622065; ClinVar: uncertain significance; called by muse, varscan2
- TTN | c.47852C>A p.P15951H (on ENST00000591111; = p.P8527H on NM_003319.4) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | PolyPhen probably damaging (0.988); catalogued as COSV100622073; called by muse, mutect2, varscan2
- TTN | c.21955C>A p.P7319T (on ENST00000591111; = p.P6392T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/92 reads (41%) | PolyPhen possibly damaging (0.802); catalogued as COSV100622074; called by muse, mutect2, varscan2
- TTN | c.12545C>A p.A4182D (on ENST00000591111; = p.A4136D on NM_003319.4) | Missense Mutation (SNP) | VAF 134/255 reads (53%) | catalogued as rs375415485, COSV100622077; called by muse, mutect2, varscan2
- UBAP1 | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99903388; called by muse, mutect2, varscan2
- USF3 | c.5423C>G p.S1808* | Nonsense Mutation (SNP) | VAF 18/374 reads (5%) | catalogued as COSV100325586; called by muse, mutect2
- USH2A | c.7270G>T p.D2424Y | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100238981; called by muse, mutect2, varscan2
- USP11 | c.431G>T p.R144L (on ENST00000218348; = p.R101L on NM_001371072.1) | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.165); catalogued as COSV54473829; called by muse, mutect2, varscan2
- USP26 | c.1900A>C p.K634Q | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV100896704; called by muse, mutect2, varscan2
- VGLL3 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV101052009; called by muse, mutect2, varscan2
- WDR72 | c.2687G>T p.R896L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs146417353, COSV64749794; called by muse, mutect2, varscan2
- WNK4 | c.3214G>C p.E1072Q | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV99890995; called by muse, mutect2
- WNT8B | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.166); catalogued as COSV100649078; called by muse, mutect2
- WRN | c.2170C>G p.Q724E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV99989516; called by muse, mutect2, varscan2
- YY1AP1 | c.478C>G p.L160V (on ENST00000295566 / NM_139118.2; = p.L83V on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV99804433; called by muse, mutect2, varscan2
- ZDHHC19 | c.121T>C p.F41L | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99579742; called by muse, varscan2
- ZMAT3 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100265287; called by muse, mutect2, varscan2
- ZMYND8 | c.1784C>T p.S595L (on ENST00000311275 / NM_001363741.2; = p.S615L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as COSV99521007; called by muse, mutect2, varscan2
- ZNF121 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.316); catalogued as COSV100248221; called by muse, mutect2, varscan2
- ZNF140 | c.1277C>G p.S426* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100166855; called by mutect2, varscan2
- ZNF200 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV101205251, COSV101205283; called by muse, varscan2
- ZNF214 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750265398, COSV99547553; called by mutect2, varscan2
- ZNF426 | c.1076G>T p.S359I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as COSV53468495; called by muse, mutect2, varscan2
- ZNF43 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100731894; called by muse, mutect2, varscan2
- ZNF451 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV62596997; called by muse, mutect2, varscan2
- ZNF536 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as rs1437031735, COSV100835183; called by muse, mutect2, varscan2
- ZNF570 | c.1073A>C p.Y358S | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100356264; called by muse, mutect2
- ZNF599 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 108/164 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV100251244; called by muse, mutect2, varscan2
- ZNF638 | c.5562G>C p.K1854N | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100039433; called by muse, mutect2
- ZNF776 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs768088062, COSV100414268; called by muse, mutect2, varscan2
- ZNF777 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.144); catalogued as COSV99925267; called by muse, mutect2, varscan2
- ZNF804B | c.3319A>T p.I1107L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100304943; called by muse, mutect2, varscan2
- ZNF91 | c.2123A>T p.H708L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100323225; called by muse, mutect2, varscan2
- ZNF93 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs1401153403, COSV100652357; called by muse, mutect2, varscan2
- ZPLD1 | c.713C>A p.T238N (on ENST00000466937 / NM_001329788.1; = p.T254N on NM_175056.2) | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100083423; called by muse, mutect2, varscan2
- ZSWIM8 | c.2898G>C p.M966I (on ENST00000605216 / NM_001242487.2; = p.M971I on NM_015037.3) | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV101290068; called by muse, mutect2, varscan2
- AC013489.1 | c.763del p.T255Pfs*97 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- CADPS2 | c.369del p.E124Nfs*14 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.2154G>T p.K718N | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GJA10 | c.106_113del p.V36Cfs*4 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel
- HTATSF1 | c.2108_2109del p.N703Rfs*5 | Frame Shift Del (DEL) | VAF 26/50 reads (52%) | called by mutect2, pindel, varscan2
- IGHV3-16 | c.285G>T p.R95S | Missense Mutation (SNP) | VAF 96/152 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); called by muse, varscan2
- IGHV3-16 | c.284G>T p.R95M | Missense Mutation (SNP) | VAF 99/155 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- IGHV3-21 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- IGKV1-5 | c.284T>A p.L95H | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MRC1 | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- MUC2 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- PCDHGB1 | c.1835T>A p.L612H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- PRAMEF17 | c.851T>G p.L284R | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SHANK2 | c.2971G>C p.E991Q | Missense Mutation (SNP) | VAF 19/342 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); called by muse, mutect2
- ACSL5 | c.582G>C p.L194= (on ENST00000354273; = p.L250= on NM_016234.3) | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV100634700; called by muse, mutect2, varscan2
- AK5 | c.1356C>A p.L452= (on ENST00000354567 / NM_174858.3; = p.L426= on NM_012093.4) | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100643190; called by muse, mutect2, varscan2
- ALMS1 | c.6927G>T p.T2309= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100043175; called by muse, mutect2, varscan2
- ALPP | c.759G>A p.K253= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as COSV67396123; called by muse, mutect2, varscan2
- AMBRA1 | c.2709C>G p.L903= (on ENST00000458649 / NM_001367468.1; = p.L813= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100094764; called by muse, mutect2
- AP3B1 | c.102C>T p.F34= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1460618374, COSV54884964, COSV54895344; called by muse, mutect2, varscan2
- AP3S1 | c.546C>A p.I182= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100372861; called by muse, mutect2, varscan2
- ARFGEF3 | c.4908C>T p.F1636= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV99294209; called by muse, mutect2, varscan2
- ARHGAP17 | c.897G>C p.L299= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99253798; called by muse, mutect2, varscan2
- ASTN1 | c.2820C>T p.P940= | Silent (SNP) | VAF 7/139 reads (5%) | catalogued as COSV100707467, COSV62497465; called by muse, mutect2
- ATXN3 | c.450T>G p.L150= | Silent (SNP) | VAF 62/257 reads (24%) | catalogued as COSV100515477; called by muse, mutect2, varscan2
- BAG6 | c.177C>T p.L59= | Silent (SNP) | VAF 21/233 reads (9%) | catalogued as rs1334729894, COSV99277363; called by muse, mutect2
- BAZ1A | c.3198T>C p.N1066= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as rs1011236829, COSV100701188; called by muse, mutect2, varscan2
- BCORL1 | c.696C>T p.P232= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as COSV99500259; called by muse, mutect2
- BTBD2 | c.1320C>T p.F440= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs763541203, COSV99724881; called by muse, mutect2, varscan2
- CACNA1B | c.1947C>T p.F649= | Silent (SNP) | VAF 26/263 reads (10%) | catalogued as rs1266032649, COSV99498665; called by muse, mutect2, varscan2
- CACNA1B | c.3702T>C p.F1234= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV99498666; called by muse, mutect2, varscan2
- CACNB4 | c.1171C>T p.L391= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99138879; called by muse, mutect2
- CAPN6 | c.681G>C p.L227= | Silent (SNP) | VAF 45/51 reads (88%) | catalogued as COSV100136972; called by muse, mutect2, varscan2
- CASP8 | c.144C>G p.L48= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99965673; called by muse, mutect2, varscan2
- CD163 | c.645A>G p.G215= | Silent (SNP) | VAF 31/227 reads (14%) | catalogued as COSV100776007; called by muse, mutect2, varscan2
- CELSR1 | c.8028C>T p.N2676= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99419211; called by muse, mutect2, varscan2
- CEP63 | c.1795C>T p.L599= | Silent (SNP) | VAF 23/490 reads (5%) | catalogued as rs149315170; called by muse, mutect2
- CHRM3 | c.381C>A p.T127= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV99699024; called by muse, mutect2, varscan2
- CHRNG | c.726C>G p.L242= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as COSV101263998; called by muse, mutect2, varscan2
- CHST4 | c.33G>T p.L11= | Silent (SNP) | VAF 61/94 reads (65%) | catalogued as COSV100632902; called by muse, mutect2, varscan2
- CLEC4A | c.456C>T p.F152= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs1565407246, COSV99983727; called by muse, mutect2, varscan2
- CNTN6 | c.36A>C p.P12= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100611395; called by muse, mutect2, varscan2
- CPNE3 | c.978C>G p.L326= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs1226912181, COSV99547882; called by muse, mutect2
- CRABP2 | c.363C>T p.I121= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV100957571; called by muse, mutect2, varscan2
- CRACR2A | c.699C>A p.I233= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99365329; called by muse, mutect2, varscan2
- CRB1 | c.219T>C p.P73= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100959152; called by muse, mutect2, varscan2
- CRYAB | c.510C>T p.T170= | Silent (SNP) | VAF 11/143 reads (8%) | catalogued as rs147970333, COSV99909912; ClinVar: likely benign; called by muse, mutect2
- CSMD3 | c.6216T>C p.D2072= (on ENST00000297405 / NM_001363185.1; = p.D1968= on NM_052900.3) | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV52280452, COSV99841474; called by muse, mutect2
- DCUN1D2 | c.486C>T p.F162= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs1566500288, COSV100215280; called by muse, mutect2, varscan2
- DDIAS | c.570C>T p.F190= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV100231334; called by muse, mutect2
- DGKB | c.915T>A p.T305= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99341705; called by muse, mutect2, varscan2
- DGKD | c.3204G>A p.Q1068= (on ENST00000264057 / NM_152879.3; = p.Q1024= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99897004; called by muse, mutect2, varscan2
- DIAPH2 | c.3111G>A p.Q1037= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as COSV100234184; called by muse, mutect2, varscan2
- DNAH11 | c.8229C>G p.A2743= | Silent (SNP) | VAF 61/195 reads (31%) | catalogued as COSV100179940; called by muse, mutect2, varscan2
- ECM2 | c.780G>A p.L260= | Silent (SNP) | VAF 27/328 reads (8%) | catalogued as COSV100755945; called by muse, mutect2
- EHD3 | c.282A>T p.T94= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100434816; called by muse, mutect2, varscan2
- ELFN2 | c.2010C>T p.L670= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV101297597; called by muse, mutect2
- EPB41L3 | c.2340C>G p.V780= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV100549797; called by muse, mutect2, varscan2
- EPHA10 | c.486G>C p.T162= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100140048, COSV60404430; called by muse, mutect2, varscan2
- FAM160A2 | c.1740G>A p.R580= (on ENST00000449352 / NM_001098794.2; = p.R594= on NM_032127.4) | Silent (SNP) | VAF 48/69 reads (70%) | catalogued as COSV99792300; called by muse, mutect2, varscan2
- FAM214B | c.1173C>G p.V391= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV100521391; called by muse, mutect2, varscan2
- FCGBP | c.7995C>T p.L2665= | Silent (SNP) | VAF 13/269 reads (5%) | called by muse, mutect2
- FEZ2 | c.648C>T p.L216= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as rs747735083, COSV100002245; called by muse, mutect2, varscan2
- FGF13 | c.303G>T p.L101= | Silent (SNP) | VAF 41/51 reads (80%) | catalogued as COSV100264468; called by muse, mutect2, varscan2
- FKRP | c.87C>T p.H29= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100586712; called by muse, mutect2, varscan2
- FLNC | c.381G>C p.L127= | Silent (SNP) | VAF 31/127 reads (24%) | catalogued as COSV100368443; called by muse, mutect2, varscan2
- FMNL2 | c.2181A>C p.T727= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV99980266; called by muse, mutect2, varscan2
- FOXJ1 | c.135C>G p.L45= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99487231; called by muse, mutect2, varscan2
- GPR176 | c.1350C>G p.S450= | Silent (SNP) | VAF 68/115 reads (59%) | catalogued as rs538072339, COSV100137354; called by muse, mutect2, varscan2
- GRIK3 | c.942G>T p.L314= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100902195; called by muse, mutect2, varscan2
- GRM5 | c.444G>C p.G148= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100553315; called by muse, mutect2, varscan2
- GRPR | c.480A>G p.K160= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100977684; called by muse, mutect2
- HBG1 | c.267G>C p.L89= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV100400676; called by muse, mutect2, varscan2
- HRH1 | c.282A>T p.S94= | Silent (SNP) | VAF 85/133 reads (64%) | catalogued as COSV101229083; called by muse, mutect2, varscan2
- IDO2 | c.1020G>T p.L340= (on ENST00000389060; = p.L353= on NM_194294.2) | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV100584878; called by muse, mutect2, varscan2
- IL10RA | c.1170G>A p.Q390= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99923180, COSV99923343; called by muse, mutect2, varscan2
- IL1R2 | c.144G>A p.L48= | Silent (SNP) | VAF 16/223 reads (7%) | catalogued as COSV100208039; called by muse, mutect2
- IQSEC3 | c.2721T>C p.L907= (on ENST00000538872 / NM_001170738.2; = p.L604= on NM_015232.1) | Silent (SNP) | VAF 11/193 reads (6%) | catalogued as COSV100407435; called by muse, mutect2
- KCNH4 | c.1533C>A p.R511= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV99237635; called by muse, mutect2, varscan2
- KCNV2 | c.480G>A p.L160= | Silent (SNP) | VAF 26/552 reads (5%) | catalogued as rs773099220, COSV101172625; called by muse, mutect2
- KIAA1549 | c.4485G>A p.P1495= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs538170892, COSV99651413, COSV99652174; called by muse, mutect2
- KSR2 | c.2472C>T p.I824= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs762091235, COSV100196084; called by muse, varscan2
- LDB3 | c.504G>C p.L168= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99555634, COSV99556096; called by muse, mutect2, varscan2
- LIG4 | c.1552C>T p.L518= | Silent (SNP) | VAF 54/83 reads (65%) | catalogued as rs909160771, COSV100799995; called by muse, mutect2, varscan2
- LRRC40 | c.393G>A p.Q131= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1346976104, COSV100918814; called by muse, mutect2, varscan2
- LYG2 | c.330T>A p.S110= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV100283723; called by muse, mutect2, varscan2
- MIEF2 | c.1113G>A p.G371= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs1425009578, COSV100544122; called by muse, mutect2, varscan2
- MON1B | c.63G>T p.T21= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99941807; called by muse, mutect2, varscan2
- MOXD1 | c.402G>A p.K134= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100381766, COSV60949236; called by muse, mutect2
- MPIG6B | c.567G>A p.Q189= (on ENST00000649779 / NM_138272.3; = p.E196K on NM_025260.4) | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV101008144; called by muse, mutect2, varscan2
- MUC16 | c.38448C>T p.F12816= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV101200578; called by muse, mutect2
- MUC4 | c.1300C>T p.L434= | Silent (SNP) | VAF 17/553 reads (3%) | catalogued as COSV100641451; called by muse, mutect2
- MYO10 | c.3159C>T p.L1053= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs367568919; called by muse, mutect2, varscan2
- NBAS | c.2148C>T p.F716= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99870885; called by muse, mutect2, varscan2
- NCCRP1 | c.573G>T p.A191= | Silent (SNP) | VAF 138/223 reads (62%) | catalogued as COSV100355852; called by muse, mutect2, varscan2
- NDC80 | c.513A>T p.T171= | Silent (SNP) | VAF 121/158 reads (77%) | catalogued as COSV99859836; called by muse, varscan2
- NIPSNAP1 | c.780C>G p.V260= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV53343733, COSV99331247; called by muse, mutect2, varscan2
- NLRP13 | c.450A>G p.E150= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs139811703; called by muse, mutect2
- NOTCH1 | c.6702G>T p.L2234= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99490051; called by muse, mutect2, varscan2
- NPAS4 | c.576T>C p.C192= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV100215127; called by muse, mutect2, varscan2
- OR10W1 | c.708C>G p.L236= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV101223650, COSV67720862; called by muse, mutect2, varscan2
- OR13A1 | c.495C>T p.A165= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs779369293, COSV65572469; called by muse, mutect2, varscan2
- OR14K1 | c.114G>A p.L38= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV99315360; called by muse, mutect2, varscan2
- OR2T8 | c.126C>G p.L42= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV100178375; called by muse, mutect2
- OR4D11 | c.675G>A p.L225= | Silent (SNP) | VAF 69/186 reads (37%) | catalogued as COSV100506599, COSV57584803; called by muse, mutect2, varscan2
- OR5D18 | c.201C>A p.L67= | Silent (SNP) | VAF 33/196 reads (17%) | catalogued as rs1412780648, COSV100450792; called by muse, mutect2, varscan2
- OR5T3 | c.321C>A p.I107= | Silent (SNP) | VAF 63/155 reads (41%) | catalogued as COSV100282873; called by muse, mutect2, varscan2
- OXER1 | c.1239C>G p.V413= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as rs1457068633, COSV99685487; called by muse, mutect2
- PC | c.681C>G p.A227= | Silent (SNP) | VAF 89/256 reads (35%) | catalogued as COSV100852297; called by muse, mutect2, varscan2
- PCDHA4 | c.1896C>T p.S632= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV100793606; called by muse, mutect2, varscan2
- PCDHGA4 | c.2226G>A p.L742= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs370951112; called by muse, mutect2, varscan2
- PCLO | c.2814C>A p.I938= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- PI4KA | c.1332C>T p.L444= | Silent (SNP) | VAF 12/191 reads (6%) | catalogued as COSV55407656; called by muse, mutect2
- PKN1 | c.1083G>A p.L361= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99661614; called by muse, mutect2, varscan2
- POTEF | c.2691C>A p.G897= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV100665141; called by muse, mutect2, varscan2
- PRDM9 | c.2208C>T p.L736= | Silent (SNP) | VAF 54/189 reads (29%) | catalogued as COSV57008138, COSV99690838; called by muse, varscan2
- PRKACG | c.525C>T p.I175= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV55242328; called by muse, mutect2, varscan2
- PSG2 | c.714T>C p.G238= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as rs1386099121, COSV100283628; called by muse, mutect2, varscan2
- PSMC2 | c.1194A>G p.R398= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV99485398; called by muse, mutect2, varscan2
- PTTG1 | c.243C>G p.L81= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99775750; called by muse, mutect2, varscan2
- RBMX2 | c.246C>G p.L82= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100564822; called by muse, mutect2, varscan2
- RET | c.2238G>C p.L746= | Silent (SNP) | VAF 46/194 reads (24%) | catalogued as COSV60692098; called by muse, mutect2, varscan2
- RFWD3 | c.2115C>T p.F705= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as COSV100736281; called by muse, mutect2, varscan2
- RFX7 | c.2007C>G p.L669= (on ENST00000559447 / NM_001368074.1; = p.L766= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs746664743, COSV100429110; called by muse, mutect2, varscan2
- RIMBP2 | c.225G>C p.A75= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99900034; called by muse, mutect2, varscan2
- RSBN1L | c.1632C>G p.T544= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100616138; called by muse, mutect2, varscan2
- SALL1 | c.1098C>T p.S366= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV99177123; called by muse, mutect2, varscan2
- SEMA3E | c.174C>G p.L58= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100319157; called by muse, mutect2, varscan2
- SENP5 | c.246C>T p.F82= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV100052156; called by muse, mutect2, varscan2
- SF3A1 | c.2292C>T p.I764= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV99305594; called by muse, mutect2, varscan2
- SHROOM4 | c.3885G>A p.E1295= | Silent (SNP) | VAF 9/152 reads (6%) | catalogued as COSV99173995; called by muse, mutect2
- SI | c.4593T>C p.C1531= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs779692980, COSV100016445; called by muse, mutect2, varscan2
- SIN3A | c.2841C>G p.L947= | Silent (SNP) | VAF 13/174 reads (7%) | catalogued as COSV100845198; called by muse, mutect2
- SLC16A3 | c.1020C>T p.F340= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs373465497, COSV58363772, COSV58366249; called by muse, mutect2, varscan2
- SLC17A3 | c.912C>T p.L304= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100399335; called by muse, mutect2, varscan2
- SLC3A1 | c.291G>T p.V97= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV99577376; called by muse, mutect2, varscan2
- SLC41A3 | c.1059G>A p.Q353= | Silent (SNP) | VAF 9/234 reads (4%) | catalogued as COSV100259775, COSV59990179; called by muse, mutect2
- SLC5A2 | c.1119C>T p.L373= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100393319; called by muse, mutect2
- SLC7A14 | c.1068G>T p.P356= | Silent (SNP) | VAF 26/196 reads (13%) | catalogued as rs758020483, COSV51577816, COSV99200710; called by muse, varscan2
- SMARCD3 | c.1023C>T p.I341= (on ENST00000262188 / NM_001003801.2; = p.I328= on NM_003078.4) | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV99223242, COSV99223352; called by muse, mutect2, varscan2
- SMG7 | c.2952T>G p.T984= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV100750463; called by muse, mutect2
- SNTB1 | c.1266C>T p.S422= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs1233511204, COSV101180054, COSV101180188; called by muse, mutect2, varscan2
- SOS1 | c.2721G>A p.L907= | Silent (SNP) | VAF 83/169 reads (49%) | catalogued as COSV101217143; called by muse, mutect2, varscan2
- SPDYE1 | c.798C>A p.P266= | Silent (SNP) | VAF 82/279 reads (29%) | catalogued as COSV99324053; called by muse, mutect2, varscan2
- SRA1 | c.378T>C p.R126= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99783938; called by muse, mutect2, varscan2
- SRBD1 | c.1356C>G p.V452= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as COSV99765344; called by muse, mutect2
- SRGAP2 | c.1920C>T p.A640= (on ENST00000624873 / NM_001170637.4; = p.A641= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as COSV99833074; called by muse, mutect2, varscan2
- STAB2 | c.3384C>G p.V1128= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV101186159; called by muse, mutect2, varscan2
- SYT11 | c.1083A>G p.E361= | Silent (SNP) | VAF 284/645 reads (44%) | catalogued as COSV100851333; called by muse, mutect2, varscan2
- TAF10 | c.612C>T p.L204= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100196533; called by muse, mutect2
- TAS1R1 | c.1209C>A p.L403= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100039511, COSV100039772, COSV59839906; called by mutect2, varscan2
- TAS2R20 | c.717C>T p.A239= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as COSV101115236; called by muse, mutect2, varscan2
- TBC1D2 | c.504C>G p.L168= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100580066; called by muse, mutect2
- TBC1D8B | c.3189G>A p.E1063= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV99344800; called by muse, mutect2, varscan2
- TEX14 | c.3030C>T p.G1010= (on ENST00000240361 / NM_001201457.2; = p.G1004= on NM_031272.5) | Silent (SNP) | VAF 78/185 reads (42%) | catalogued as COSV99542961; called by muse, mutect2, varscan2
- TMBIM4 | c.105G>C p.L35= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99660432; called by muse, mutect2, varscan2
- TMEM131 | c.5223C>T p.L1741= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs370135727; called by muse, mutect2, varscan2
- TMEM132B | c.120G>T p.T40= | Silent (SNP) | VAF 55/183 reads (30%) | catalogued as COSV54745118, COSV54746980; called by muse, mutect2, varscan2
- TMEM175 | c.663C>G p.P221= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99298038, COSV99298176; called by muse, mutect2, varscan2
- TMEM196 | c.231C>A p.I77= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV101337511; called by mutect2, varscan2
- TRAF7 | c.1428G>C p.R476= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV100399706; called by muse, mutect2, varscan2
- TRHR | c.627C>A p.V209= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100304963; called by muse, mutect2, varscan2
- TRPC7 | c.414G>T p.T138= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100725836; called by muse, mutect2, varscan2
- TTN | c.78765T>A p.T26255= (on ENST00000591111; = p.T18831= on NM_003319.4) | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100622063; called by muse, mutect2, varscan2
- TTN | c.71490G>A p.L23830= (on ENST00000591111; = p.L16406= on NM_003319.4) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs72646902, COSV100622064; called by muse, mutect2, varscan2
- TTN | c.58678C>A p.R19560= (on ENST00000591111; = p.R12136= on NM_003319.4) | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as rs764243269, CM121826, COSV100622067, COSV60174862; called by muse, mutect2, varscan2
- TUB | c.1008G>A p.L336= (on ENST00000299506 / NM_177972.3; = p.L391= on NM_003320.4) | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs759600983, COSV100210371; called by muse, mutect2, varscan2
- UBR4 | c.4308G>A p.Q1436= | Silent (SNP) | VAF 19/191 reads (10%) | catalogued as COSV100921371; called by muse, mutect2, varscan2
- USF3 | c.5688T>A p.P1896= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV100325583; called by muse, mutect2, varscan2
- VPS13B | c.11499T>A p.L3833= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV100662768; called by muse, mutect2, varscan2
- WDR24 | c.366G>A p.V122= (on ENST00000248142; = p.V60= on NM_032259.4) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1326471934, COSV99555888; called by muse, mutect2, varscan2
- XKR3 | c.417A>T p.T139= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV100509328; called by muse, mutect2, varscan2
- YIF1A | c.651C>G p.L217= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs878951599, COSV61012222; called by muse, mutect2, varscan2
- ZMYND8 | c.2730C>T p.N910= (on ENST00000311275 / NM_001363741.2; = p.N884= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as rs779785588, COSV53685859; called by muse, mutect2, varscan2
- ZNF527 | c.1782C>G p.V594= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV100648760, COSV62229380; called by muse, mutect2, varscan2
- ZNF564 | c.450C>T p.F150= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100213237; called by muse, mutect2, varscan2
- ZNF746 | c.438C>G p.S146= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100502316, COSV100502532; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83394G>A | Intron (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- ASPH | c.322+4786G>C | Intron (SNP) | VAF 7/51 reads (14%) | catalogued as rs1303958825, COSV100727698; called by muse, mutect2
- BCAR1 | chr16:75267967 C>T | 5'Flank (SNP) | VAF 12/18 reads (67%) | catalogued as COSV101108528; called by muse, mutect2, varscan2
- CGREF1 | c.718+10G>C | Intron (SNP) | VAF 126/420 reads (30%) | catalogued as COSV99565328; called by muse, varscan2
- DCHS2 | n.607A>G | RNA (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100252553; called by muse, mutect2
- DCX | c.-22-430C>G | Intron (SNP) | VAF 14/136 reads (10%) | catalogued as rs1324852945, COSV100576647; called by muse, mutect2
- EIF4A2 | c.771+184G>T | Intron (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99961286; called by muse, mutect2, varscan2
- FAM183BP | n.1059C>A | RNA (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- GCNT2 | c.*2C>G | 3'UTR (SNP) | VAF 18/28 reads (64%) | catalogued as COSV99399451; called by muse, mutect2, varscan2
- IGHV1-12 | n.90G>T | RNA (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- OR2W5 | n.412T>G | RNA (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- PITPNC1 | c.683-5388T>C | Intron (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100083850; called by muse, mutect2, varscan2
- SFRP1 | c.544+1783G>T | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99617603; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928794 C>T | 3'Flank (SNP) | VAF 9/103 reads (9%) | catalogued as COSV60485807; called by muse, mutect2
- SMARCA2 | c.3982-1788G>A | Intron (SNP) | VAF 15/100 reads (15%) | catalogued as rs369140373; called by muse, mutect2, varscan2
- SNORD115-19 | n.37A>C | RNA (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- SSPOP | n.10363C>A | RNA (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100947734; called by muse, mutect2, varscan2
- TGIF1 | c.-292C>T | 5'UTR (SNP) | VAF 21/417 reads (5%) | catalogued as COSV100394919; called by muse, mutect2
- UCHL5 | c.-212G>C | 5'UTR (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100814666; called by muse, mutect2, varscan2
